Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042792-09A.3 (aliquot TARGET-15-SJMPAL042792-09A.3-01D) from TARGET case TARGET-15-SJMPAL042792, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,527 days).
Specimen TARGET-15-SJMPAL042792-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227ffaba-9150-45b6-9cf1-0cc9d8317fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042792-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042792-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9155bcc-a978-403b-8a46-2e84636bbbf7

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, 3'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRM1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756528929, COSV61006252; called by muse, mutect2, varscan2
- DST | c.19597G>T p.A6533S (on ENST00000361203 / NM_001374722.1; = p.A4230S on NM_015548.5) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV55012008; called by muse, mutect2
- EFL1 | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as COSV51602993; called by muse, varscan2
- HLX | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs865817214; called by muse, mutect2
- SIAH1 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV53527451; called by muse, varscan2
- ABCC1 | c.3936C>A p.H1312Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- FLI1 | c.722-6C>A | Splice Region (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- MACF1 | c.4193T>G p.L1398* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- MYO19 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OAS3 | c.3060C>A p.D1020E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2
- SCUBE1 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLGAP3 | c.639C>A p.G213= | Silent (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- THSD7A | c.1344C>T p.R448= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs776774107, COSV101448556; called by mutect2, varscan2
- AC245033.1 | c.1174+738G>A | Intron (SNP) | VAF 15/26 reads (58%) | catalogued as rs989141339; called by muse, mutect2, varscan2
- CICP28 | chr7:56812130 C>T | 3'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as rs57107924; called by muse, mutect2
